Somatic mutation profile of tumor specimen TCGA-BP-4167-01A (aliquot TCGA-BP-4167-01A-02D-1386-10) from TCGA case TCGA-BP-4167, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 60.0 years (21,901 days).
Specimen TCGA-BP-4167-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71013ce6-6676-4367-8df3-6f723ee28ca0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4167-11A (Solid Tissue Normal), aliquot TCGA-BP-4167-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50685196-8ab4-450e-bc2c-98340ec944ea

The open-access MAF lists 62 somatic variants for this specimen: 52 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 45, Silent 10, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMDHD1 | c.194G>C p.G65A | Missense Mutation (SNP) | VAF 35/578 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV57139974; called by muse, mutect2
- ANO3 | c.263A>G p.N88S | Missense Mutation (SNP) | VAF 66/774 reads (9%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); catalogued as rs1565028129, COSV56786992; called by muse, mutect2
- ASZ1 | c.463T>C p.Y155H | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1277979474, COSV52915596; called by muse, mutect2, varscan2
- ATCAY | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV56658355, COSV99040873; called by muse, varscan2
- C12orf60 | c.347A>G p.K116R | Missense Mutation (SNP) | VAF 26/355 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1421023100, COSV57452993; called by muse, mutect2
- CARMIL2 | c.2199G>T p.L733F | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV58030733; called by muse, mutect2
- CELSR1 | c.4735T>C p.C1579R | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53097562; called by muse, mutect2, varscan2
- CIC | c.1337A>T p.E446V | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV50647828; called by muse, mutect2, varscan2
- COL11A1 | c.2709+1G>T p.X903_splice | Splice Site (SNP) | VAF 16/203 reads (8%) | catalogued as COSV62175168; called by muse, mutect2
- DGKB | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 67/487 reads (14%) | catalogued as COSV51761564, COSV51781556; called by muse, mutect2, varscan2
- DZIP1L | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 123/574 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV59522885; called by mutect2, varscan2
- ERP27 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV56763134, COSV56764531; called by muse, mutect2, varscan2
- ESR2 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs774742997, COSV50829603; called by muse, mutect2
- GAPVD1 | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 20/307 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52926475; called by muse, mutect2
- GPHN | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.932); catalogued as COSV59490195; called by muse, mutect2, varscan2
- GPR101 | c.1154G>A p.S385N | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV53238408, COSV53240013; called by muse, mutect2, varscan2
- HIP1R | c.2201A>G p.E734G | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs1170082150, COSV53444008; called by muse, mutect2
- INTS1 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV67179229; called by muse, mutect2
- KAT6A | c.3938A>G p.D1313G | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.156); catalogued as COSV55910880; called by muse, mutect2, varscan2
- KIF26B | c.4024A>T p.I1342F | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.125); catalogued as COSV63649073; called by muse, mutect2
- KRT26 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59415450; called by muse, mutect2
- LHFPL4 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as COSV55004367; called by muse, mutect2
- LRP1B | c.12871G>T p.D4291Y | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV67261164, COSV67279342; called by muse, mutect2
- MACIR | c.553G>C p.V185L | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.304); catalogued as COSV60635723; called by muse, mutect2
- MEGF10 | c.2380T>A p.Y794N | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57254844; called by muse, mutect2
- MUC16 | c.14507G>A p.G4836E | Missense Mutation (SNP) | VAF 36/432 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.783); catalogued as rs1199121356, COSV67485664; called by muse, mutect2
- MYBPC1 | c.1735C>T p.P579S (on ENST00000550270 / NM_206820.2; = p.P604S on NM_002465.4) | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.074); catalogued as COSV62256644; called by muse, mutect2
- OR3A3 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV99351425; called by muse, mutect2, varscan2
- OSBPL11 | c.701T>G p.L234* | Nonsense Mutation (SNP) | VAF 48/352 reads (14%) | catalogued as COSV56175888; called by muse, mutect2, varscan2
- PCK2 | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53750266; called by muse, mutect2
- PITRM1 | c.2040G>T p.M680I | Missense Mutation (SNP) | VAF 38/574 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99829231; called by muse, mutect2
- PPP1R7 | c.485A>G p.K162R | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs917372684, COSV52146609; called by muse, mutect2
- PRRC2C | c.3941G>A p.R1314Q (on ENST00000367742; = p.R1312Q on NM_015172.4) | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs762928818, COSV58911292; called by muse, mutect2, varscan2
- PSG5 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 56/369 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV61655103; called by muse, mutect2, varscan2
- RSRC2 | c.715T>G p.L239V | Missense Mutation (SNP) | VAF 39/706 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV59206584; called by muse, mutect2
- SCGB3A2 | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 28/622 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV57023738; called by muse, mutect2
- SNX19 | c.2422G>C p.D808H | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV56288057; called by muse, mutect2
- SPTA1 | c.68A>C p.E23A | Missense Mutation (SNP) | VAF 45/327 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV63757773; called by muse, mutect2, varscan2
- SYNE1 | c.26306A>T p.E8769V (on ENST00000367255 / NM_182961.4; = p.E8721V on NM_033071.3) | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55071000; called by muse, mutect2, varscan2
- TAF7L | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 69/260 reads (27%) | catalogued as COSV61256601, COSV61257803; called by muse, mutect2, varscan2
- TEKT3 | c.1467C>G p.F489L | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV58627519, COSV58629247; called by muse, mutect2
- TMTC3 | c.2725C>T p.R909C | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs747294917, COSV57125847; called by muse, mutect2, varscan2
- TTN | c.12190G>A p.E4064K (on ENST00000591111; = p.E4018K on NM_003319.4) | Missense Mutation (SNP) | VAF 14/136 reads (10%) | catalogued as COSV59953065; called by muse, mutect2, varscan2
- TTN | c.8650A>G p.I2884V (on ENST00000591111; = p.I2838V on NM_003319.4) | Missense Mutation (SNP) | VAF 8/144 reads (6%) | PolyPhen benign (0.069); catalogued as rs1390184716, COSV60273046; called by muse, mutect2
- USHBP1 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV53105602; called by muse, mutect2, varscan2
- WDR74 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53933164; called by muse, mutect2, varscan2
- ZMAT1 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 9/235 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV65659724; called by muse, mutect2
- ZNF200 | c.1006T>A p.F336I | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV67724193; called by muse, mutect2, varscan2
- ZNF621 | c.873T>A p.Y291* | Nonsense Mutation (SNP) | VAF 22/227 reads (10%) | catalogued as COSV59458883; called by muse, mutect2
- ZNF98 | c.1283A>C p.H428P | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63339123; called by muse, mutect2, varscan2
- ADAM30 | c.2154del p.K719Nfs*107 | Frame Shift Del (DEL) | VAF 71/672 reads (11%) | called by mutect2, pindel, varscan2
- COL11A1 | c.618del p.F206Lfs*19 | Frame Shift Del (DEL) | VAF 64/630 reads (10%) | called by mutect2, pindel, varscan2
- CTDP1 | c.2496T>A p.S832= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV50007969; called by muse, mutect2
- FILIP1 | c.2571T>A p.P857= | Silent (SNP) | VAF 30/255 reads (12%) | catalogued as rs745722891, COSV52738284; called by muse, mutect2, varscan2
- GTSE1 | c.1281C>A p.G427= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV101483216, COSV71889636; called by muse, mutect2, varscan2
- JAG2 | c.1179G>A p.P393= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs147768578; called by muse, mutect2, varscan2
- MAGEC3 | c.159C>T p.A53= | Silent (SNP) | VAF 33/268 reads (12%) | catalogued as COSV74217417; called by muse, mutect2, varscan2
- PPIL4 | c.555A>G p.Q185= | Silent (SNP) | VAF 38/544 reads (7%) | catalogued as COSV53568395; called by muse, mutect2
- RAG2 | c.774C>T p.V258= | Silent (SNP) | VAF 14/153 reads (9%) | catalogued as COSV57559206; called by muse, mutect2, varscan2
- SRSF2 | c.468A>G p.R156= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV57974816; called by mutect2, varscan2
- TTN | c.47280C>A p.I15760= (on ENST00000591111; = p.I8336= on NM_003319.4) | Silent (SNP) | VAF 32/468 reads (7%) | catalogued as COSV60272983; called by muse, mutect2
- ZNF423 | c.1035T>A p.G345= (on ENST00000563137 / NM_001379286.1; = p.G337= on NM_015069.4) | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV52200939; called by muse, mutect2, varscan2
